Somatic mutation profile of tumor specimen 0DJM98 from CCDI case PBBWZZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 13.7 years (5,021 days).
Specimen 0DJM98: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 411cc84c-72f6-453e-ae6f-b03f32652a05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJM8J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0a2e6eb-095a-4f73-bf22-fa655cf4c2ee

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL133500.1 | c.1400C>T p.T467I | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated, low confidence (0.17); catalogued as rs1259030494; called by muse, varscan2
- FLT4 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs773021479; called by muse, varscan2
- NLRC3 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473124254, COSV57090364, COSV57092707; called by muse, varscan2
- SARM1 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 137/368 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1271687605; called by muse, varscan2
- SIK3 | c.2732G>T p.S911I (on ENST00000445177 / NM_001366686.2; = p.S869I on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV99407916; called by muse, varscan2
- TAS2R3 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 211/536 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756949695, COSV56092757; called by muse, varscan2
- DIP2C | c.1786A>T p.M596L | Missense Mutation (SNP) | VAF 220/554 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- MYOCD | c.620G>T p.R207I | Missense Mutation (SNP) | VAF 191/487 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, varscan2
- VDAC2 | c.835A>C p.I279L | Missense Mutation (SNP) | VAF 169/537 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, varscan2
- ANAPC15 | c.150C>T p.N50= | Silent (SNP) | VAF 163/453 reads (36%) | called by muse, varscan2
- KCTD8 | c.594C>T p.G198= | Silent (SNP) | VAF 39/113 reads (35%) | called by muse, varscan2
- KLHL34 | c.1458C>T p.G486= | Silent (SNP) | VAF 43/102 reads (42%) | called by muse, varscan2
- CCDC61 | c.231+17C>T | Intron (SNP) | VAF 43/228 reads (19%) | catalogued as rs374851742; called by muse, varscan2
- RPH3AL | c.-37+690A>G | Intron (SNP) | VAF 174/482 reads (36%) | called by muse, varscan2
- UBE2D2 | c.121-13T>G | Intron (SNP) | VAF 155/367 reads (42%) | called by muse, varscan2
- ZMAT2 | c.*23T>C | 3'UTR (SNP) | VAF 106/234 reads (45%) | called by muse, varscan2
